Somatic mutation profile of tumor specimen TCGA-AJ-A3EM-01A (aliquot TCGA-AJ-A3EM-01A-11D-A20S-09) from TCGA case TCGA-AJ-A3EM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 70.0 years (25,557 days).
Specimen TCGA-AJ-A3EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65261e3d-1b96-40af-864c-f814aeb4f358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3EM-11A (Solid Tissue Normal), aliquot TCGA-AJ-A3EM-11A-11D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/654c06c5-8f11-42f0-8127-f63f6bfda25a

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 5, Frame Shift Ins 2, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.2964G>T p.K988N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs759534806, COSV100864896; called by muse, mutect2, varscan2
- ATP5F1A | c.1546G>C p.V516L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV104387997, COSV56361844; called by muse, mutect2, varscan2
- BCL9L | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100600270; called by muse, mutect2, varscan2
- BNIPL | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs764413830, COSV54845752; called by muse, mutect2, varscan2
- CYP2E1 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429276; called by muse, mutect2, varscan2
- DBH | c.620T>A p.L207* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | catalogued as COSV99708154; called by muse, mutect2, varscan2
- DCLRE1B | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99871199; called by muse, mutect2
- FCN1 | c.341-1G>A p.X114_splice | Splice Site (SNP) | VAF 41/53 reads (77%) | catalogued as COSV100878982; called by muse, mutect2, varscan2
- FUT4 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100708064, COSV100708209; called by muse, mutect2, varscan2
- GGT5 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99571960; called by muse, mutect2, varscan2
- H1-4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs1443547361; called by mutect2, varscan2
- HAUS6 | c.2855A>C p.D952A | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV100997919; called by muse, mutect2, varscan2
- HEATR9 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368450766; called by muse, mutect2, varscan2
- HLCS | c.1975G>T p.V659F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100358665; called by muse, mutect2, varscan2
- IL21R | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100560648; called by muse, mutect2, varscan2
- JRK | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101401179; called by muse, mutect2
- MICAL1 | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1295129674, COSV99238206; called by muse, mutect2, varscan2
- MOK | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 50/148 reads (34%) | catalogued as COSV99513691; called by muse, mutect2, varscan2
- MPEG1 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs746216310, COSV57089051, COSV99916028; called by muse, mutect2
- MYCL | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.734); catalogued as COSV65693641; called by muse, mutect2, varscan2
- OR2T3 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs749274432, COSV100613459; called by muse, mutect2
- OR2T3 | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100613460; called by muse, mutect2
- PKHD1 | c.7663A>T p.S2555C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100584808; called by muse, mutect2, varscan2
- PPP1R13B | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99162985; called by muse, mutect2, varscan2
- PSG8 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.951); catalogued as COSV100126686; called by muse, mutect2, varscan2
- RCN3 | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99571489; called by muse, mutect2, varscan2
- SDK2 | c.3323C>A p.A1108D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV101168967; called by muse, mutect2
- SLC16A3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV101125928; called by muse, mutect2
- SMARCC1 | c.2587G>T p.E863* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV99593604; called by muse, mutect2, varscan2
- SPG7 | c.1001T>A p.V334D (on ENST00000268704; = p.V341D on NM_003119.4) | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99245505; called by muse, mutect2, varscan2
- TMPRSS11B | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219546; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1751T>G p.V584G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV100709241; called by muse, mutect2, varscan2
- WWP2 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776834403, COSV100598828; called by muse, mutect2, varscan2
- XKR7 | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101629309; called by muse, mutect2, varscan2
- ZNF449 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1314279484, COSV59346969; called by muse, mutect2, varscan2
- DDX11 | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.729); called by muse, mutect2
- SHROOM2 | c.391dup p.A131Gfs*49 | Frame Shift Ins (INS) | VAF 29/180 reads (16%) | called by mutect2, pindel, varscan2
- TIGD7 | c.1169dup p.Q392Tfs*18 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- ADGRE2 | c.540C>T p.C180= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV100216571; called by muse, mutect2, varscan2
- DCC | c.4053T>A p.P1351= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV101473592, COSV71433022; called by muse, mutect2, varscan2
- HYDIN | c.12375C>A p.R4125= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- IGSF9B | c.135C>T p.C45= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs374604489; called by muse, mutect2, varscan2
- MGAT5B | c.681C>A p.P227= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as COSV100049056; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, varscan2
- PABPC3 | c.1308C>A p.A436= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99880180; called by muse, varscan2
- PCIF1 | c.588C>T p.P196= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100976120; called by muse, mutect2, varscan2
- PI4KA | c.3066C>T p.S1022= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs533263946, COSV99748974; called by muse, mutect2, varscan2
- PTPRM | c.870C>G p.L290= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100161028; called by muse, mutect2, varscan2
- SPINK5 | c.144G>A p.K48= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV56251623; called by muse, mutect2, varscan2
- SUPT20HL1 | c.729G>A p.S243= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs750935915; called by muse, mutect2, varscan2
- XPNPEP2 | c.702G>C p.P234= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs781765581, COSV100941302; called by muse, mutect2, varscan2
- EPHA6 | c.1895-8871A>G | Intron (SNP) | VAF 19/38 reads (50%) | catalogued as COSV101065932; called by muse, mutect2, varscan2
- TBCC | c.*1G>C | 3'UTR (SNP) | VAF 38/82 reads (46%) | catalogued as COSV99774034; called by muse, mutect2, varscan2
